FM case AD9662 — Foundation Medicine Adult Cancer Clinical Dataset (FM-AD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Epithelial Neoplasms, NOS.
https://portal.gdc.cancer.gov/cases/a2592237-db4a-420b-bb99-ae6942a48fc2

Female, 23.2 years: Small cell carcinoma, NOS (ICD-O-3 8041/3); metastasis biopsied or resected from the ovary. Tumor nuclei on the sequenced sample's slide: 80% (pathologist estimate recorded by GDC). Sample type: Metastatic.
